Surgical pathology report (de-identified scan), TCGA case TCGA-41-2572, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Christiana Healthcare, specimen TCGA-41-2572-01A (Primary Tumor).

[REDACTED] (GBM)

SPECIMEN

- A. Left occipital tumor biopsy
- B. Left occipital tumor
- C. Left occipital tumor

CLINICAL NOTES

--

FROZEN SECTION DIAGNOSIS

- A. Brain, left occipital tumor, biopsy: Glioblastoma multiforme.

GROSS DESCRIPTION

- A. Specimen is received unfixed labeled "left occipital tumor biopsy FS" and consists of multiple pieces of red and brown soft tissue measuring 1.2 cm in greatest aggregate dimension.
- B. Specimen is received in formalin labeled "left occipital tumor" and consists of multiple pieces of tan and red soft tissue, measuring 2.2 x 1.9 x 0.3 cm in aggregate. AS-3
- C. Specimen was received fresh by [REDACTED] and was taken for research purposes. Specimen C was a piece of red soft tissue measuring approximately 1.5 cm in greatest dimension.

MICROSCOPIC DESCRIPTION

Sections show a hypercellular glioma with mitotic figures, some new vessel formation and areas of necrosis. The histologic features are those of glioblastoma multiforme.

3x2, 8, 14

DIAGNOSIS

- A, B. Brain, left occipital tumor, biopsy: Glioblastoma multiforme.

Source: NCI Genomic Data Commons file 14e32e71-e7b5-4efa-b518-bf45a97eb4db (TCGA-41-2572.B6C486C9-5FC6-4DF1-8EC8-877C8FD96E49.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).